Somatic mutation profile of tumor specimen C3L-00928-03 (aliquot CPT0063570009) from CPTAC case C3L-00928, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 58.6 years (21,418 days).
Specimen C3L-00928-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e79e77e1-81c0-46eb-ba2d-47a181010676.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00928-31 (Blood Derived Normal), aliquot CPT0065280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef4e6b56-ef2f-4256-8b48-871f30f14813

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Ins 2, Intron 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 19/168 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 21/295 reads (7%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- DOHH | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs368504297; called by muse, mutect2
- GNAS | c.185T>G p.I62S | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55685506; called by muse, mutect2, varscan2
- KCNH7 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs139430414; called by muse, mutect2
- LRTM1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs779554165, COSV55513807; called by muse, mutect2, varscan2
- OAF | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs748586285, COSV61110148; called by muse, mutect2
- SSC5D | c.4553G>A p.R1518H | Missense Mutation (SNP) | VAF 53/507 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs748017648, COSV67476898; called by muse, mutect2, varscan2
- ZIC4 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs998956801, COSV67172689; called by muse, mutect2
- ARHGEF28 | c.2624T>C p.F875S | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARMC5 | c.380dup p.T128Dfs*59 | Frame Shift Ins (INS) | VAF 64/692 reads (9%) | called by mutect2, pindel
- ARMCX5-GPRASP2 | c.1310del p.V437Afs*29 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- ITK | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 57/506 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR2 | c.7637A>T p.D2546V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JARID2 | c.3383dup p.W1129Vfs*58 | Frame Shift Ins (INS) | VAF 14/168 reads (8%) | called by mutect2, pindel
- OR8B2 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PCDHB2 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.242); called by muse, mutect2
- SETX | c.5313T>G p.N1771K | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SVEP1 | c.8835A>C p.K2945N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TRIP12 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- TRPC6 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDHR1 | c.1353G>A p.K451= | Silent (SNP) | VAF 44/484 reads (9%) | called by muse, mutect2
- COL5A1 | c.840C>T p.Y280= | Silent (SNP) | VAF 44/483 reads (9%) | catalogued as rs765347784, COSV65669270, COSV65675824; called by muse, mutect2
- EXD3 | c.1422G>A p.T474= | Silent (SNP) | VAF 20/260 reads (8%) | catalogued as rs370478324; called by muse, mutect2
- HOXB1 | c.288T>A p.S96= | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- PKD1L1 | c.6666A>G p.E2222= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2
- LMBR1L | c.72+730G>A | Intron (SNP) | VAF 8/143 reads (6%) | catalogued as rs1380526903; called by muse, mutect2
